Surgical pathology report (de-identified scan), TCGA case TCGA-ZJ-AAX8, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site NCI HRE Branch, specimen TCGA-ZJ-AAX8-01A (Primary Tumor).

ACCT#: [REDACTED] DOB: [REDACTED]

Specimen #: [REDACTED] Dr: [REDACTED]
Date Obtained: [REDACTED] Date Received: [REDACTED] Date Printed: [REDACTED]

CLINICAL HISTORY:
ICD-9: 627.1

*ICD 6.3
Carcinoma, squamous cell, large cell,
non-keratinizing 80723
Site: Cervix NOS C53.9
JW 6/13/14*

SPECIMEN/PROCEDURE:
1. CERVIX - BX

IMPRESSION:
CERVIX, 5 O'CLOCK, BIOPSY:
Invasive squamous cell carcinoma, large cell nonkeratinizing type, moderately differentiated.

Dictated by: [REDACTED]
Entered: [REDACTED]

GROSS DESCRIPTION:
Received labeled with the patient's name and medical record number, is a pale pink-tan irregular tissue fragment that is 0.7 x 0.5 x 0.4 cm. There is a large amount of adherent red-brown hemorrhagic material. Specimen is entirely submitted in one cassette.

Dictated by: [REDACTED]
Entered: [REDACTED]

CPT Codes:
CERVICAL BIOPSY (1)/88305/3997100

ICD9 Codes:
180.9

Electronically Signed by: [REDACTED]

Patient: [REDACTED] Age/Sex: [REDACTED] /F Acct#: [REDACTED] Unit#: [REDACTED]

Source: NCI Genomic Data Commons file 4279dc3b-9b4f-42cb-9f96-383372f8411c (TCGA-ZJ-AAX8.8CCFD872-3834-4769-A6C6-809E77108BE5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).